Somatic mutation profile of tumor specimen MP2PRT-PAUTIB-TMP1-A (aliquot MP2PRT-PAUTIB-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUTIB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (874 days).
Specimen MP2PRT-PAUTIB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9282a7de-d35b-4a83-abde-8ca0eb603aa5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTIB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTIB-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9474347-64d5-43af-8d51-fb761fb67cbd

The open-access MAF lists 85 somatic variants for this specimen: 67 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 12, Nonsense Mutation 6, Intron 2, 3'Flank 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 58/232 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM900213, COSV52684909, COSV52740428, COSV52828352; called by muse, mutect2, varscan2
- ADIPOQ | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57859114; called by muse, mutect2, varscan2
- AKT1S1 | c.654C>G p.I218M (on ENST00000344175 / NM_001098633.4; = p.I238M on NM_032375.5) | Missense Mutation (SNP) | VAF 58/480 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59273976; called by muse, mutect2, varscan2
- CPB2 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1260780467; called by muse, mutect2
- CPNE4 | c.1563G>C p.K521N | Missense Mutation (SNP) | VAF 17/396 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1470885505; called by muse, mutect2
- DPYSL3 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747491194, COSV58324930; called by muse, mutect2, varscan2
- EPHA7 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 20/405 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV65193240; called by muse, mutect2
- ETFDH | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs748289922, CM024520; called by muse, mutect2
- FRMPD4 | c.1648G>C p.D550H | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV66224624; called by muse, mutect2
- HSD3B7 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs765046765; called by muse, mutect2
- L3HYPDH | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV99070629; called by muse, mutect2
- LDLRAD3 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 77/435 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs151059364; called by muse, mutect2, varscan2
- MUC16 | c.13417G>T p.G4473W | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV67483302; called by muse, mutect2
- MYRF | c.2854C>T p.H952Y (on ENST00000278836 / NM_001127392.3; = p.H917Y on NM_013279.4) | Missense Mutation (SNP) | VAF 21/643 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV53888701; called by muse, mutect2
- NOTCH4 | c.3655C>T p.R1219W | Missense Mutation (SNP) | VAF 41/758 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs202197092; called by muse, mutect2
- OR2J3 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65848643; called by muse, mutect2, varscan2
- PPIL2 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as rs1349575122, COSV58604737; called by muse, mutect2
- SERPINF1 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 23/671 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99628872; called by muse, mutect2
- SPAG17 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 52/424 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs769357421; called by muse, mutect2, varscan2
- SSX5 | c.380C>T p.P127L (on ENST00000347757 / NM_175723.1; = p.P168L on NM_021015.4) | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs1457526301; called by muse, mutect2
- TBX4 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1349553581, COSV53608026; called by muse, mutect2
- TEKT4 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 33/296 reads (11%) | catalogued as rs545808608, COSV54623997; called by muse, mutect2, varscan2
- WSCD2 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs371743603, COSV99774753; called by muse, mutect2, varscan2
- ARID2 | c.1507G>C p.A503P | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- CASP4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- CCDC144A | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 65/495 reads (13%) | called by mutect2, pindel, varscan2
- CHRNA2 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COMMD1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- CWF19L2 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 17/403 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2
- DEF6 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 21/681 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- DENND6A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 12/321 reads (4%) | called by muse, mutect2
- DHX57 | c.3030G>C p.E1010D | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- DOP1B | c.6441C>G p.I2147M | Missense Mutation (SNP) | VAF 19/627 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2
- EIF1AY | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2
- FANCM | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 18/470 reads (4%) | called by muse, mutect2
- GCNA | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HCN1 | c.1865T>G p.L622R | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- INO80D | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- KDR | c.3874G>T p.E1292* | Nonsense Mutation (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- KRT7 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 12/409 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.356); called by muse, mutect2
- LAMB3 | c.2490G>C p.L830F | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- LRRC47 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- MAN1C1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MAPK8IP1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2
- MCMDC2 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.026); called by muse, mutect2
- MVB12A | c.26C>G p.S9W | Missense Mutation (SNP) | VAF 41/492 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- MYO18A | c.5899G>A p.E1967K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- NEK8 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUDT19 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PALMD | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 21/389 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDCD7 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PJA2 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 12/361 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- POU5F2 | c.750G>C p.Q250H | Missense Mutation (SNP) | VAF 23/421 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- PPP1R7 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- RPTN | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- RRAGD | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 17/424 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2
- SELP | c.2187C>G p.I729M | Missense Mutation (SNP) | VAF 27/417 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- SLC37A1 | c.489C>T p.V163= | Splice Region (SNP) | VAF 15/289 reads (5%) | called by muse, mutect2
- STAT4 | c.1793G>C p.R598T | Missense Mutation (SNP) | VAF 37/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC45B | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- VAC14 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- VPS18 | c.1323G>C p.E441D | Missense Mutation (SNP) | VAF 16/397 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- ZDBF2 | c.1211C>G p.S404* | Nonsense Mutation (SNP) | VAF 17/410 reads (4%) | called by muse, mutect2
- ZNF160 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.236); called by muse, mutect2
- ZNF609 | c.3373G>T p.E1125* | Nonsense Mutation (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- ZNFX1 | c.5386G>C p.E1796Q | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.479); called by muse, mutect2
- ADRA2A | c.231C>T p.R77= | Silent (SNP) | VAF 31/717 reads (4%) | catalogued as COSV54528282; called by muse, mutect2
- BCO2 | c.240C>G p.L80= | Silent (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
- CFAP57 | c.2808G>A p.K936= | Silent (SNP) | VAF 24/458 reads (5%) | called by muse, mutect2
- CHD5 | c.132C>T p.P44= | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as rs138961166, COSV52410245; called by muse, mutect2
- FBXL6 | c.96G>A p.P32= | Silent (SNP) | VAF 31/872 reads (4%) | catalogued as rs1429375753, COSV100095605, COSV57351743; called by muse, mutect2
- RALGAPA2 | c.5406G>T p.V1802= | Silent (SNP) | VAF 13/351 reads (4%) | called by muse, mutect2
- RNF213 | c.13968C>T p.L4656= | Silent (SNP) | VAF 13/225 reads (6%) | called by muse, mutect2
- SCML4 | c.1200G>A p.L400= | Silent (SNP) | VAF 21/452 reads (5%) | called by muse, mutect2
- TAFA2 | c.165G>A p.K55= | Silent (SNP) | VAF 52/361 reads (14%) | called by muse, mutect2, varscan2
- TNIK | c.3246G>A p.L1082= | Silent (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- TYR | c.435C>T p.I145= | Silent (SNP) | VAF 13/401 reads (3%) | called by muse, mutect2
- ZNFX1 | c.4890G>A p.L1630= | Silent (SNP) | VAF 25/428 reads (6%) | called by muse, mutect2
- ADGRL2 | c.3101+869G>A | Intron (SNP) | VAF 21/289 reads (7%) | catalogued as COSV54663528, COSV99589403; called by muse, mutect2
- ATG16L1 | c.-23G>C | 5'UTR (SNP) | VAF 35/676 reads (5%) | called by muse, mutect2
- FBRS | chr16:30659730 C>T | 5'Flank (SNP) | VAF 74/577 reads (13%) | called by muse, varscan2
- SATB1 | c.212-616G>A | Intron (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- ZFP14 | chr19:36331530 G>A | 3'Flank (SNP) | VAF 15/366 reads (4%) | called by muse, mutect2
- ZNRD2 | chr11:65572459 C>G | 3'Flank (SNP) | VAF 17/399 reads (4%) | called by muse, mutect2
